Surgical pathology report (de-identified scan), TCGA case TCGA-DU-7009, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-7009-01A (Primary Tumor).

PATHOLOGICAL DIAGNOSIS:

BRAIN BIOPSY: OLIGODENDROGLIOMA. (MIB-1: 4%)

ADDITIONAL DIAGNOSIS:

ADDITIONAL TISSUE: OLIGODENDROGLIOMA (MIB-1: < 0.5%).

Operation/Specimen: UPDATED REPORT

Brain tumor #1, frozen section. Brain tissue #2, frozen section.

Clinical History and Pre-Op Dx:

GROSS PATHOLOGY: Multiple 0.3-0.5 cm tissue fragments. Frozen section
diagnosis: Glioma. In #1 and 3.

MICROSCOPIC: Sections show an oligodendroglioma involving the white matter and the cortex. The tumor is moderately hypercellular with mild pleomorphism. Mitotic figures, endothelial hyperplasia and necrosis are not identified. This is a low grade oligodendroglioma, grade A in

ADDITIONAL MICROSCOPIC: Sections of the additional tissue retrieved from the tumor bank that was removed from the radiologically enhancing area show a low grade oligodendroglioma which is similar to the original tissue fragment. Anaplastic features are not seen. The proliferative index (MIB-1) is less than 0.5%.

Source: NCI Genomic Data Commons file 6bda7f1d-35b4-46ae-ab24-15559472404d (TCGA-DU-7009.BC350788-3A70-47D5-B2EF-45DEEBD89FA0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).